Somatic mutation profile of tumor specimen TCGA-BT-A20U-01A (aliquot TCGA-BT-A20U-01A-11D-A14W-08) from TCGA case TCGA-BT-A20U, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 70.5 years (25,761 days).
Specimen TCGA-BT-A20U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b512b13-1b37-45bf-964c-0d6c8d06b40b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20U-11A (Solid Tissue Normal), aliquot TCGA-BT-A20U-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6a9069b-c460-42e8-b8d6-6fdbce23257b

The open-access MAF lists 85 somatic variants for this specimen: 70 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 14, Nonsense Mutation 8, Translation Start Site 1, In Frame Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553488015, COSV67960750, COSV67961406; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SETD5 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as rs1421204500, COSV56715022; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ACTA2 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.419); catalogued as COSV56517388; called by muse, mutect2, varscan2
- ALCAM | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1437229076, COSV60251671; called by muse, mutect2, varscan2
- AOX1 | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.034); catalogued as COSV65982894; called by muse, mutect2, varscan2
- ATP1A4 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1338469550, COSV63624383; called by muse, mutect2, varscan2
- B4GALNT2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55927390, COSV55927666; called by muse, mutect2, varscan2
- BCLAF1 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV62143814; called by muse, mutect2, varscan2
- CNTLN | c.3454G>C p.D1152H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.33); catalogued as COSV52076868, COSV52088201; called by muse, mutect2, varscan2
- CRNKL1 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 5/119 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV66106409; called by muse, mutect2
- CTNND2 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs781372774, COSV58908112, COSV58908709; called by muse, mutect2, varscan2
- CXorf21 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.198); catalogued as COSV66763011; called by muse, mutect2, varscan2
- DAAM1 | c.2287G>C p.E763Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs1251308743; called by muse, mutect2
- DCSTAMP | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773599990, COSV52577499, COSV99886910; called by muse, mutect2, varscan2
- EIF2AK3 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.7); catalogued as COSV57550152; called by muse, mutect2, varscan2
- EMSY | c.831G>A p.K277= | Splice Region (SNP) | VAF 10/46 reads (22%) | catalogued as COSV58263695; called by muse, mutect2, varscan2
- F12 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV53692259; called by muse, mutect2, varscan2
- FAT1 | c.4609C>T p.Q1537* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV71676076; called by muse, mutect2, varscan2
- FGD1 | c.400C>A p.R134S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.145); catalogued as COSV64308048, COSV64309225; called by muse, mutect2, varscan2
- FRMD8 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as rs368973734; called by muse, mutect2, varscan2
- GFAP | c.1313C>G p.S438C (on ENST00000253408 / NM_001363846.2; = p.S398C on NM_002055.5) | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as CM083521, CM0911218, COSV53652120; called by muse, mutect2, varscan2
- HEXA | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as CD910531; called by muse, mutect2, varscan2
- HNRNPU | c.2190G>C p.W730C (on ENST00000283179; = p.W792C on NM_004501.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51692882; called by muse, mutect2, varscan2
- IPO8 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.703); catalogued as rs781176618, COSV56243937; called by muse, mutect2, varscan2
- IRAK4 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV71210736; called by muse, mutect2, varscan2
- LANCL2 | c.211C>G p.H71D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV54650911; called by muse, mutect2, varscan2
- LIPE | c.2779G>C p.E927Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV54924256, COSV54925896; called by muse, mutect2, varscan2
- MAPK8 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV64409074, COSV64410253, COSV64411402; called by muse, mutect2, varscan2
- MAPK8 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV64410265; called by muse, mutect2
- MBNL1 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV56825722; called by muse, mutect2, varscan2
- MCM4 | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV50627834; called by muse, mutect2, varscan2
- MET | c.2590G>A p.D864N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV59265354; called by muse, mutect2, varscan2
- MRPS35 | c.521G>C p.R174T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV50011853; called by muse, mutect2, varscan2
- MUC16 | c.32971C>G p.L10991V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.186); catalogued as COSV67480123; called by muse, mutect2
- MYBPC1 | c.1128G>C p.K376N (on ENST00000550270 / NM_206820.2; = p.K401N on NM_002465.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62251754, COSV62255535; called by muse, mutect2, varscan2
- MYH7 | c.4004C>T p.S1335L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs397516199, COSV62516785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOC | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV50676446; called by muse, mutect2, varscan2
- MYOM1 | c.3964G>C p.D1322H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55296743; called by muse, mutect2, varscan2
- NEXMIF | c.1493C>G p.S498* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV50030335; called by muse, mutect2, varscan2
- PKNOX2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as rs200769767, COSV100021570, COSV53550482; called by muse, mutect2, varscan2
- PLEKHA6 | c.662G>C p.R221T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV55337058; called by muse, mutect2, varscan2
- PRAG1 | c.2794G>A p.G932R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.583); catalogued as rs370977684; called by muse, mutect2, varscan2
- RFC1 | c.3403G>C p.D1135H (on ENST00000381897 / NM_001363496.2; = p.D1134H on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as COSV56467871; called by muse, mutect2, varscan2
- RPAP1 | c.1050G>C p.Q350H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.192); catalogued as COSV58541052; called by muse, mutect2, varscan2
- RPAP1 | c.915G>C p.K305N | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58541060; called by muse, varscan2
- RPAP1 | c.786G>C p.L262F | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58541070; called by muse, varscan2
- RUSC1 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV52741531; called by muse, mutect2
- RYR2 | c.10517G>A p.R3506Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs748805290, COSV100769225, COSV63670201; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.5154G>C p.K1718N | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs267599809, COSV56566599, COSV56574297; called by muse, mutect2, varscan2
- SLC39A3 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV54118584; called by mutect2, varscan2
- SLC5A9 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52584769; called by muse, mutect2, varscan2
- SREBF1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs149599437; called by muse, mutect2, varscan2
- TUBA3C | c.1137C>G p.S379R | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV68029144; called by muse, mutect2, varscan2
- UTRN | c.3542G>A p.R1181K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as COSV62341838; called by muse, mutect2, varscan2
- VCAN | c.9859T>G p.Y3287D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54111303; called by muse, mutect2, varscan2
- WIZ | c.4483G>A p.E1495K (on ENST00000673675 / NM_001371589.1; = p.E400K on NM_021241.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1387762877, COSV54605463; called by muse, mutect2
- ZNF415 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs150561707; called by muse, mutect2, varscan2
- ZNF710 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51564570; called by muse, mutect2, varscan2
- ZNF75D | c.164T>A p.F55Y | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66133150; called by muse, mutect2, varscan2
- ZZEF1 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67559015; called by muse, mutect2, varscan2
- ACACA | c.6987C>G p.I2329M | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); called by muse, mutect2
- ADGRL2 | c.3482C>G p.S1161* (on ENST00000370717 / NM_001366005.1; = p.S1148* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- ATP13A2 | c.2419G>C p.D807H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COL24A1 | c.3959G>C p.R1320T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.119); called by muse, mutect2
- LRRC41 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- LRRC47 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- PYGO1 | c.366C>A p.Y122* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.1127G>T p.W376L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- TP63 | c.563_571del p.K188_A190del | In Frame Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- ARHGAP12 | c.2121C>T p.V707= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- CDK1 | c.885G>A p.K295= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV57349978; called by muse, mutect2, varscan2
- GSAP | c.531T>C p.I177= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV57531702; called by muse, mutect2, varscan2
- HCN3 | c.531C>T p.L177= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs767345999, COSV64234655, COSV64235158; called by muse, mutect2, varscan2
- HIP1R | c.1152G>A p.L384= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- KIF26B | c.2217C>T p.V739= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV63646557; called by muse, mutect2, varscan2
- NUMB | c.1353C>G p.V451= (on ENST00000355058; = p.V440= on NM_003744.5) | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV53721133; called by muse, mutect2, varscan2
- PRPF6 | c.1947G>A p.V649= | Silent (SNP) | VAF 64/288 reads (22%) | catalogued as COSV53874844; called by muse, mutect2, varscan2
- RPTOR | c.3801G>C p.L1267= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV60813616; called by muse, mutect2
- SHCBP1 | c.447C>T p.L149= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV57649305; called by muse, mutect2, varscan2
- SPTLC3 | c.1110C>T p.T370= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs373903172; called by muse, mutect2, varscan2
- TMEM26 | c.846C>T p.I282= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV53263214, COSV99515660; called by muse, mutect2, varscan2
- TRIL | c.231C>T p.F77= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV59867571; called by muse, mutect2, varscan2
- UBE2J2 | c.117G>A p.S39= | Silent (SNP) | VAF 15/239 reads (6%) | catalogued as rs1261236341, COSV59571836; called by muse, mutect2
- DTWD2 | c.218+13637C>T | Intron (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
